CPTAC case C3L-02382 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3f74668a-15a0-4d28-b6df-6a4a04f5e2af

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1953; Vital status: Dead; Days to death: 1,726 days (4.7 years); Year of death: 2022; Country of birth: United States.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Endometrium; Age at diagnosis: 63.8 years (23,312 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G2; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,726 days (4.7 years); Progression or recurrence: no; Days to last follow up: 1,693 days (4.6 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.5 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 3; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 360 days; Disease response: Tumor Free.
- Days to follow up: 815 days (2.2 years); Disease response: Tumor Free.
- Days to follow up: 1,088 days (3.0 years); Disease response: Tumor Free; ECOG performance status: 2.
- Days to follow up: 1,501 days (4.1 years); Disease response: Tumor Free; ECOG performance status: 1.
- Days to follow up: 1,501 days (4.1 years); Disease response: Complete Response; ECOG performance status: 1.
- Days to follow up: 1,693 days (4.6 years); Disease response: Tumor Free; ECOG performance status: 1.

Other clinical attributes
- Weight: 106.59 kg; Height: 167.64 cm; BMI: 37.93; Hormonal contraceptive use: Former User.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Tobacco smoking onset year: 1978; Alcohol history: Yes; Alcohol intensity: Non-Drinker; Exposure duration years: 44.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02382-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 69 days; Initial weight: 115 mg; Time between excision and freezing: 27 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02382-26: Section location: Anterior endometrium; Percent tumor nuclei: 90; Percent necrosis: 2.
- Sample C3L-02382-17: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 69 days; Time between excision and freezing: 27 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02382-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 69 days; Method of sample procurement: Blood Draw.
